Somatic mutation profile of tumor specimen TCGA-13-0893-01B (aliquot TCGA-13-0893-01B-01W-0494-09) from TCGA case TCGA-13-0893, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 48.1 years (17,573 days).
Specimen TCGA-13-0893-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d42b050b-78a2-49c4-b09f-7f8997378fcf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0893-10A (Blood Derived Normal), aliquot TCGA-13-0893-10A-01W-0494-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6649b3fd-7ee2-491b-8f7c-a2efc8f66ef6

The open-access MAF lists 100 somatic variants for this specimen: 77 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 19, Intron 3, Nonsense Mutation 3, Frame Shift Del 3, In Frame Del 2, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 21/30 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC090517.4 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51001842; called by muse, mutect2, varscan2
- ADAMTSL3 | c.585C>G p.I195M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54473590; called by muse, mutect2, varscan2
- ADCY8 | c.3023T>A p.L1008Q | Missense Mutation (SNP) | VAF 196/2274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99652028; called by muse, mutect2
- ADGRG4 | c.2508T>G p.N836K | Missense Mutation (SNP) | VAF 32/992 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99795331; called by muse, mutect2
- ANAPC1 | c.5678C>G p.S1893C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100594682; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7147G>A p.A2383T | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51860611; called by muse, mutect2, varscan2
- ANKRD30A | c.978T>G p.D326E (on ENST00000611781; = p.D270E on NM_052997.2) | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.417); catalogued as rs372199195, COSV64623545; called by muse, mutect2, varscan2
- ARPC3 | c.107C>A p.T36K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV57400736; called by muse, mutect2, varscan2
- ASAP2 | c.1888C>G p.L630V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV99856132; called by muse, mutect2
- ATXN2L | c.2347C>G p.P783A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV57380374; called by mutect2, varscan2
- BAZ1B | c.3098A>G p.H1033R | Missense Mutation (SNP) | VAF 159/1382 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as COSV59995231; called by muse, mutect2, varscan2
- BMERB1 | c.190_200del p.R64Gfs*6 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | catalogued as COSV55513544; called by mutect2, pindel, varscan2
- C1orf162 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 57/337 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59059784; called by muse, mutect2, varscan2
- CCDC102B | c.1276C>T p.L426F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as rs756836181, COSV60156408; called by muse, mutect2, varscan2
- CHN1 | c.208T>A p.Y70N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69299167; called by muse, mutect2, varscan2
- CNKSR3 | c.887C>A p.S296Y | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV70481780; called by muse, mutect2, varscan2
- COL14A1 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 70/474 reads (15%) | catalogued as COSV52871235; called by muse, mutect2, varscan2
- CRIP3 | c.400+1G>T p.X134_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99240316; called by muse, mutect2, varscan2
- CRIP3 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99240318; called by muse, mutect2, varscan2
- CUL2 | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 23/80 reads (29%) | catalogued as COSV66081526; called by muse, mutect2, varscan2
- CYP11B1 | c.158T>A p.L53Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52830895; called by muse, mutect2, varscan2
- DRAXIN | c.759G>T p.E253D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.097); catalogued as COSV53842704; called by muse, mutect2, varscan2
- DUSP19 | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1401653445, COSV61194093; called by muse, mutect2, varscan2
- FAM126B | c.1039G>T p.A347S | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.142); catalogued as COSV53775605; called by muse, mutect2, varscan2
- FAM183A | c.243G>T p.K81N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV58923488; called by muse, mutect2, varscan2
- FER1L6 | c.992T>G p.M331R | Missense Mutation (SNP) | VAF 72/613 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV67553304; called by muse, mutect2, varscan2
- FREM2 | c.2902G>A p.V968I | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV54855337; called by muse, mutect2, varscan2
- GFPT2 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53813558; called by muse, mutect2, varscan2
- GLI3 | c.2008C>G p.Q670E | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.079); catalogued as COSV67890604; called by muse, mutect2, varscan2
- ITGA4 | c.754G>T p.G252* | Nonsense Mutation (SNP) | VAF 10/348 reads (3%) | catalogued as COSV51999001; called by muse, mutect2
- KIAA1549L | c.5347T>C p.Y1783H (on ENST00000321505; = p.Y2080H on NM_012194.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV100381446; called by muse, mutect2
- KRTAP10-11 | c.496T>C p.S166P | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV58179737; called by muse, mutect2, varscan2
- MPDZ | c.5322G>C p.M1774I | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV59925968; called by muse, mutect2, varscan2
- MTHFD2L | c.254G>T p.S85I (on ENST00000395759 / NM_001144978.2; = p.S27I on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV57471091; called by muse, mutect2, varscan2
- MYH13 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.422); catalogued as COSV52845869; called by muse, mutect2, varscan2
- NARS2 | c.411G>C p.E137D | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV55256563; called by muse, mutect2, varscan2
- NEUROD1 | c.115A>T p.K39* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV54551493; called by muse, mutect2, varscan2
- NPM2 | c.127A>G p.R43G | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV99235720; called by muse, mutect2
- OR6V1 | c.731C>A p.T244K | Missense Mutation (SNP) | VAF 81/302 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV69237726; called by muse, mutect2, varscan2
- OR8B3 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.313); catalogued as rs1207579079, COSV63542316; called by muse, mutect2, varscan2
- P2RY13 | c.935T>C p.M312T | Missense Mutation (SNP) | VAF 107/848 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56400703; called by muse, mutect2, varscan2
- PARP2 | c.545A>C p.D182A | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV51642556; called by muse, mutect2, varscan2
- PCSK5 | c.2448G>T p.Q816H | Missense Mutation (SNP) | VAF 83/304 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.189); catalogued as COSV65096477, COSV65098197; called by muse, mutect2, varscan2
- PLGRKT | c.138G>C p.Q46H | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56352936; called by muse, mutect2, varscan2
- PRKCA | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 55/72 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1303564138, COSV52597996; called by muse, mutect2, varscan2
- RCSD1 | c.256A>T p.I86F | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63261481; called by muse, mutect2, varscan2
- RGS4 | c.320T>A p.L107Q | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63358584; called by muse, mutect2, varscan2
- RNF20 | c.1281G>C p.E427D | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV66662603; called by muse, mutect2, varscan2
- RTL4 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 327/488 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100465722, COSV61206926, COSV61207477; called by muse, mutect2, varscan2
- RYR2 | c.9244C>A p.H3082N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV100770408, COSV63659423, COSV63719949; called by muse, mutect2, varscan2
- SETD2 | c.4976G>T p.G1659V | Missense Mutation (SNP) | VAF 139/393 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57454480; called by muse, mutect2, varscan2
- SLC13A1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs775622587, COSV99520829; called by muse, mutect2
- SLC16A4 | c.293C>T p.T98I | Missense Mutation (SNP) | VAF 148/368 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV63917527; called by muse, mutect2, varscan2
- SLC9A4 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 25/353 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV99762976; called by muse, mutect2
- SOS1 | c.3551C>A p.P1184H | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67678015; called by muse, mutect2, varscan2
- SPTBN1 | c.2884C>T p.L962F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV61685798, COSV61695279; called by muse, mutect2, varscan2
- TESK1 | c.479C>G p.A160G | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52412627; called by muse, mutect2, varscan2
- TIMELESS | c.355G>C p.A119P | Missense Mutation (SNP) | VAF 113/268 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57515974; called by muse, mutect2, varscan2
- TMEM74 | c.857C>A p.T286K | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as COSV52462730, COSV52465072; called by muse, varscan2
- TMEM94 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as rs1159052938, COSV58600823; called by muse, mutect2, varscan2
- TNRC6B | c.3367T>G p.S1123A (on ENST00000454349 / NM_001162501.2; = p.S1070A on NM_015088.3) | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100109615; called by muse, mutect2
- TRIM21 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 166/896 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs1331877094, COSV54346594; called by muse, mutect2, varscan2
- TTN | c.65347A>G p.K21783E (on ENST00000591111; = p.K14359E on NM_003319.4) | Missense Mutation (SNP) | VAF 66/393 reads (17%) | PolyPhen probably damaging (0.994); catalogued as COSV60402633; called by muse, mutect2, varscan2
- UBQLN3 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs201719446, COSV61164777; called by muse, mutect2, varscan2
- UIMC1 | c.80C>A p.S27Y | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV65895386; called by muse, mutect2, varscan2
- VPS13C | c.2803C>G p.L935V (on ENST00000644861 / NM_020821.3; = p.L892V on NM_017684.5) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.684); catalogued as COSV51151246, COSV51173359; called by muse, mutect2, varscan2
- XIRP2 | c.9254A>G p.E3085G (on ENST00000628543; = p.E3260G on NM_152381.6) | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV54739856; called by muse, mutect2, varscan2
- ZNF549 | c.998T>A p.V333E (on ENST00000376233 / NM_001199295.2; = p.V320E on NM_153263.2) | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53728169; called by muse, mutect2, varscan2
- CDH17 | c.827_858del p.K276Rfs*29 | Frame Shift Del (DEL) | VAF 88/883 reads (10%) | called by mutect2, pindel
- GPR50 | c.841_882del p.F281_Y294del | In Frame Del (DEL) | VAF 38/145 reads (26%) | called by mutect2, pindel
- IGHV1-46 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 107/415 reads (26%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- LGR4 | c.1975_2003del p.L659Gfs*16 | Frame Shift Del (DEL) | VAF 21/204 reads (10%) | called by mutect2, pindel
- LPA | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 452/3851 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- PRKCE | c.104C>G p.T35S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.006); called by mutect2, varscan2
- RSPO1 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.422); called by muse, mutect2
- TADA3 | c.841_876del p.P281_A292del | In Frame Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- APOB | c.630G>C p.G210= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV51956484; called by muse, mutect2, varscan2
- BCAS1 | c.837T>C p.A279= | Silent (SNP) | VAF 74/524 reads (14%) | catalogued as COSV65090100; called by muse, mutect2, varscan2
- C7 | c.2157C>T p.Y719= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs563401809, COSV57482557; called by muse, mutect2, varscan2
- DST | c.2625T>A p.I875= (on ENST00000361203 / NM_001374722.1; = p.I549= on NM_001723.6) | Silent (SNP) | VAF 32/200 reads (16%) | catalogued as COSV55045708; called by muse, mutect2, varscan2
- FOXS1 | c.558T>A p.P186= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV54068786; called by muse, mutect2
- HRH2 | c.240G>C p.L80= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV51576766; called by muse, mutect2, varscan2
- IGHG2 | c.798G>T p.P266= | Silent (SNP) | VAF 29/104 reads (28%) | called by muse, mutect2, varscan2
- MED12L | c.5133G>A p.L1711= | Silent (SNP) | VAF 63/384 reads (16%) | catalogued as rs530265514, COSV99852844; called by muse, mutect2, varscan2
- MED26 | c.768G>T p.V256= | Silent (SNP) | VAF 3/7 reads (43%) | catalogued as COSV54663624; called by muse, mutect2
- NLRP12 | c.1515C>T p.N505= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV60756882; called by muse, mutect2, varscan2
- OR1L6 | c.870G>A p.G290= (on ENST00000373684; = p.G254= on NM_001004453.2) | Silent (SNP) | VAF 57/306 reads (19%) | catalogued as COSV59029879; called by muse, mutect2, varscan2
- PKD1L1 | c.450C>T p.G150= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99219508; called by muse, mutect2, varscan2
- RC3H1 | c.318A>G p.L106= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV51224540; called by muse, mutect2, varscan2
- SEMA3D | c.1395T>C p.D465= | Silent (SNP) | VAF 49/401 reads (12%) | catalogued as rs1051449442, COSV52406963; called by muse, mutect2, varscan2
- SLC5A9 | c.771C>A p.T257= | Silent (SNP) | VAF 116/226 reads (51%) | catalogued as COSV52586282; called by muse, mutect2, varscan2
- SMG5 | c.1902C>T p.R634= | Silent (SNP) | VAF 56/296 reads (19%) | catalogued as rs776297053, COSV62438328; called by muse, mutect2, varscan2
- SPR | c.558G>T p.L186= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99318039; called by muse, mutect2
- ST6GAL2 | c.192C>T p.A64= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1303047480, COSV64532581; called by muse, mutect2, varscan2
- TSHZ3 | c.2655G>A p.S885= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs774294393, COSV53671978; called by muse, mutect2, varscan2
- ACSL6 | c.577+248_577+250delinsCAGT | Intron (INS) | VAF 3/31 reads (10%) | called by mutect2*, pindel
- COL11A1 | c.898-251A>T | Intron (SNP) | VAF 79/224 reads (35%) | catalogued as COSV62201208; called by muse, mutect2, varscan2
- MIR7-3 | n.9G>C | RNA (SNP) | VAF 70/231 reads (30%) | called by muse, mutect2, varscan2
- NEBL | c.164+46338A>T | Intron (SNP) | VAF 87/172 reads (51%) | catalogued as COSV65799310; called by muse, mutect2, varscan2
